Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9I9, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9I9-01A (Primary Tumor).

[page 1 of 3]
Pathology Report

ICD-C-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head C25.0
JSD 4/16/14

Final Diagnosis

- A. GALLBLADDER, CHOLECYSTECTOMY:
Chronic cholecystitis.
- B. HEAD OF PANCREAS, PORTION OF STOMACH AND DUODENUM,
PANCREATICOUDUODENECTOMY (WHIPPLE):
Invasive pancreatic ductal adenocarcinoma, moderately differentiated.
(See Key Pathological Findings).
Lymph nodes (22), negative for malignancy.
Pancreatic, common bile duct, retroperitoneal, uncinate/vascular, proximal gastric, and
distal duodenal margins, free of tumor.
Pancreatic margin has focal pancreatic intraepithelial neoplasia (PanIN-1a).
Pathologic TN stage: pT3 N0
- C. LYMPH NODE, LEFT HEPATIC ARTERY, EXCISION:
Lymph node (1), negative for malignancy.

I, _____, NO the attending pathologist, personally reviewed all
slides and / or materials and rendered the final diagnosis. Electronically
Signed Out by _____

Comment

Review of the operative notes documents that _____ received notification of the frozen section
margin status.

Key Pathological Findings

B: Pancreas Exocrine

SPECIMEN:

Head of pancreas
Duodenum
Stomach
Gallbladder

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

[page 2 of 3]
Greatest dimension of solid component: 3.5 cm
Additional dimensions: 2.5 cm
HISTOLOGIC TYPE:
Ductal adenocarcinoma
HISTOLOGIC GRADE:
G2: Moderately differentiated
MICROSCOPIC TUMOR EXTENSION:
Tumor invades ampulla of Vater or sphincter of Oddi
Tumor invades duodenal wall
Tumor invades peripancreatic soft tissues
MARGINS:
Margins uninvolved by invasive carcinoma
TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):
No prior treatment
LYMPH-VASCULAR INVASION:
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN0: No regional lymph node metastasis
Number examined: 23
Number involved: 0
DISTANT METASTASIS (pM)
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 2)
Chronic pancreatitis
Lobular atrophy
CLINICAL HISTORY:
Not specified

Specimen(s) Received

A GALLBLADDER
B WHIPPLE 2FS
C LEFT HEPATIC ARTERY LYMPH NODE

Clinical History

PANCREATIC CANCER

Preoperative Diagnosis

Not given.

Intraoperative Consultation

B. WHIPPLE:
FSB1. Bile duct margin with no evidence of malignancy.
FSB2. Pancreatic margin with low-grade PanIN and no evidence of malignancy.

[page 3 of 3]
Comment: This frozen section diagnosis/result was communicated to and acknowledged by Dr _____ in OR _____ at _____.

I, _____ M.D., have performed the intraoperative consultations and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "gallbladder." The specimen consists of a clubbed shaped gallbladder (9.0 x 3.0 x 3.0 cm). The cystic duct is identified (0.3 cm in length). The serosa is gray-yellow with a focus of shaggy adherent fibroadipose tissue. The remainder of the mucosa is smooth. On opening, the gallbladder contains a moderate amount of green viscous bile. No calculi are grossly appreciated. The mucosa surface is green-yellow and velvet like. No tissue is submitted to the Tissue Procurement Laboratory. Representative sections are submitted as:

- A1: Cystic duct.
- A2: Gallbladder.

B. The specimen is received fresh labeled "Whipple, staple equals vascular margin, frozen section on margins." The specimen consists of head of pancreas (6.0 x 3.5 x 3.5 cm), a portion of the stomach (8.0 cm along the greater curvature and 4.0 cm along the lesser curvature), and a portion of the duodenum (16.0 cm in length and 6.0 cm in greatest circumference). The serosa of the duodenum and stomach is gray-tan and smooth with a moderate amount of adherent pericolic/perigastric adipose tissue. Margins of resection are identified as the pancreatic margin, which is submitted for frozen section as FSB1, the common bile duct margin which is submitted for frozen section as FSB2. The superior mesenteric vein groove is marked yellow ink and entirely submitted, the retroperitoneal margin is marked with blue ink and entirely submitted, and the vascular margin/uncinate process is marked with green ink and submitted tangentially entirely. The lumen of the duodenum is filled with a moderate amount of green visceral bile. The mucosa surface exhibits no polyps or nodularity. The ampulla of Vater is not prominent. The pancreas reveals an indurated, ill-defined mass (3.5 x 2.5 x 2.5 cm), grossly coming to within 1 cm of the pancreatic margin of resection and 0.5 cm of soft tissue margin of resection. The mass does cause partial occlusion of the pancreatic duct and dilation of the common bile duct. Cut surface of the tumor is gray-white and smooth. There is gross evidence of possible involvement of the duodenal wall. The remaining pancreatic parenchyma is grossly unremarkable. The stomach is grossly free of tumor and exhibits normal rugae. A section of the adjacent adipose tissue isolates 3 possible lymph nodes adjacent to the pancreas. A representative section of the tumor is submitted to the Tissue Procurement Laboratory. Two representative frozen sections are taken and submitted as FSB1 and FSB2.

Permanent sections are submitted as:

- B3: Mirror image of tumor submitted to Tissue Bank.
- B4-B5: The superior mesenteric artery groove.
- B6-B7: Retroperitoneal margin of resection.
- B8: The stapled vascular margin of resection submitted tangentially.
- B9-B10: Tangential gastric margin of resection.
- B11: Tangential duodenal margin of resection.
- B12: Tumor showing its relationship to the pancreatic duct.
- B13: Tumor showing its relationship to the common bile duct.
- B14: Tumor showing its relationship to the ampulla of Vater.
- B15: Tumor showing its relationship to duodenal mucosa.
- B16-B17: Tumor showing its relationship to pancreatic parenchyma.
- B18: Grossly unremarkable gastric mucosa.
- B19: Grossly unremarkable duodenal mucosa.
- B20: Possible lymph nodes isolated at pancreas.
- B21-B30: Entire adipose tissue adjacent to pancreas.
- B31-B42: Entire adipose tissue at the greater curvature.

C. The specimen is received fresh labeled "left hepatic artery lymph nodes." The specimen consists of a single moderately firm, brown-tan irregular lymph node (2.0 x 1.0 x 1.0 cm). The lymph node is serially sectioned and entirely submitted as C1.

Source: NCI Genomic Data Commons file 528fb759-352f-4c0c-b056-e1046abb9d42 (TCGA-3A-A9I9.E0B2E9CA-3563-4D29-BB48-57A77AC810CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).